Surgical pathology report (de-identified scan), TCGA case TCGA-60-2704, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2704-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

*******Addendum*******

SPECIMEN(S): A. 4 R L.N.
B. 4-R LYMPH NODE
C. 4 L L.N.
D. 4-L LYMPH NODE
E. LEVEL 7
F. 4 R L.N.
G. LEVEL VII
H. R. MIDDLE LOBE LESION
I. RT. UPPER LOBE
J. LEVEL 10R LYMPH NODE
K. LEVEL 4R LYMPH NODE
L. NO SPECIMEN REC'D
M. LEVEL 4R LYMPH NODE
N. POSTERIOR LEVEL 10
O. LEVEL 7 LYMPH NODE

CLINICAL HISTORY:

None

PRE-OPERATIVE DIAGNOSIS:

Right upper lobe mass

FROZEN SECTION DIAGNOSIS:

FSA LYMPH NODE-negative for tumor

FSC LYMPH NODE-negative for tumor

FSE LYMPH NODE-negative for tumor

FSE LYMPH NODE-negative for tumor

[page 2 of 6]
[REDACTED]

FSH RIGHT MIDDLE LOBE LUNG-calcified necrotizing granuloma. Comment: Tissue difficult to cut in cryostat.

[REDACTED]

I. RIGHT LOBE

I1: Bronchial margin of resection free of tumor

I2: Section from tumor: squamous cell carcinoma reported [REDACTED]

[REDACTED]

GROSS DESCRIPTION:

A. 4R LYMPH NODE:

Received fresh is a singular lymph node measuring 1.5x1.3x0.4cm. Submitted entirely in cassette FSA.

B. 4R LYMPH NODE

Specimen consists of two fragments of tan red soft tissue measuring 1.3x0.5x0.3cm. The other measures 1.6x1x0.4cm. All submitted in one cassette labelled B1.

C. 4L LYMPH NODE:

Received fresh is a singular lymph node measuring 0.6x0.5x0.2cm. Submitted entirely in cassette FSC.

D. 4L LYMPH NODE

Specimen consists of a minute fragment of tan brown tissue measuring 2.4x0.2x0.1cm. Submitted in one cassette labelled D1.

E. LEVEL 7:

Received fresh is a portion of lymph node measuring 0.5cm in diameter. Submitted entirely in 1 cassette labelled FSE.

F. 4R LYMPH NODE:

Received fresh are possible pieces of lymphoid tissue measuring in aggregate 0.8cm. Submitted entirely in 1 cassette labelled FSF.

G. LEVEL 7 LYMPH NODE

Specimen consists of black brown tissue that measures 0.5x0.6x0.1cm. Submitted in one cassette labelled G1.

H. RIGHT MIDDLE LOBE LESION:

Received fresh is a wedge resection of lung tissue measuring 4.5x2.5x1.0cm. Central portion of the specimen is a firm palpable mass located 0.5cm from the midline. On sectioning the mass is calcified with yellow central necrotic area. Portion of nodule is sent for frozen section as FSH. The wedge has a stapled margin measuring 3.5cm in length. The pleural surface is inked green. Other section of the specimen is put in cassette labelled H2. Random lung in H3.

[REDACTED]

I. RIGHT UPPER LOBE:

Specimen consists of right upper lung lobe measuring 18x9x7.5cm and weighing 273gm. The pleural surface is smooth and glistening without any induration. A mass that is located on one side of the specimen. This mass is well circumscribed and measures 8x7x6cm with tan and white

[REDACTED]

[page 3 of 6]
[REDACTED]

cut surface and central areas of necrosis. It is approximately 2.5cm from the bronchial margin of resection and it is approximately 2.7cm from pleural surface. Specimen is submitted as follows:

Bronchial margin FS11

Tumor FS12

I3-I6: tumor sections

I7-I8: lymph nodes

I9: atelectatic lung

J. LEVEL 10 LYMPH NODE

Specimen consists of brown red soft tissue measuring 2x1.1x0.7cm. Submitted in toto in one cassette labelled J1.

K. 4R LYMPH NODE

Specimen consists of two fragments of tan red soft tissue that measure 1.6x1.2x0.3cm. The other measures 1x0.5x0.2cm. All submitted in one cassette labelled K1.

L. NO SPECIMEN RECEIVED. CONFIRMED WITH OR

M. LEVEL 4R LYMPH NODE

Specimen consists of one lymph node that measures 2.2x1x0.9cm. and shows anthracotic pigment. Specimen is submitted in toto in M1.

N. SUPERIOR LEVEL 10 LYMPH NODE

Specimen consists of one lymph node that measures 1.3x1x0.4cm. Specimen is submitted in one cassette labelled N1.

[REDACTED]

O. LEVEL 7 LYMPH NODE

Specimen consists of tan red soft tissue that measures 2.1x.8x.6cm. that is bisected and submitted on one cassette labelled O1.

DIAGNOSIS:

A. LYMPH NODE, 4R, EXCISION;

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

B. LYMPH NODE, 4R, EXCISION:

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

C. LYMPH NODE, 4L, EXCISION:

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

D. LYMPH NODE, 4L, EXCISION:

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

E. LYMPH NODE, LEVEL 7, EXCISION:

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

F. LYMPH NODE, RIGHT 4R, EXCISION;

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

G. LYMPH NODE, LEVEL VII, EXCISION:

-LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

H. LUNG, RIGHT MIDDLE LESION, EXCISION:

CALCIFIED GRANULOMA

[REDACTED]

[page 4 of 6]
I. LUNG, RIGHT UPPER LOBE, EXCISION:

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF LUNG
- TUMOR SIZE 8X7X6CM.
- BRONCHIAL MARGINS OF RESECTION, NO TUMOR SEEN
- ONE OF FOUR HILAR LYMPH NODES, POSITIVE FOR METASTASIS (1/4)

J. LUNG, LEVEL 10R, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

K. LUNG, LEVEL 4R, EXCISION:

- TWO LYMPH NODES, NEGATIVE FOR METASTASIS (0/2)

L. NO SPECIMEN RECEIVED

M. LYMPH NODE, 4R, EXCISION:

- ONE LYMPH NODE, POSITIVE FOR METASTASIS (1/1)

N. LYMPH NODE, LEVEL 10, POSTERIOR, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

O. LYMPH NODE, LEVEL 7, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

Lung template

1. Tumor type: Squamous cell carcinoma
2. Histologic grade: Poorly differentiated
3. Tumor location: Central
4. Tumor size: 8x7x6cm.
5. Angiolymphatic invasion: Absent
6. Perineural invasion: Absent
7. Involvement of main stem bronchus: Absent
8. Bronchial margin: Negative
9. Visceral pleural margin: Negative
10. Hilar lymph nodes: Positive (1/6)
Other: (#4R and L, VII): 1/10 (specimen labelled "M")
11. In-situ carcinoma: Absent
12. Pathologic stage: pT2N1Mx
13. Non-neoplastic lung: None
-

[page 5 of 6]
ADDENDUM:

The pathologic stage on the template is amended from N1 to N2.

AMENDED DIAGNOSIS:

LUNG, RIGHT UPPER LOBE, RESECTION:

-PATHOLOGIC STAGE pT2N2Mx

[page 6 of 6]
ADDENDUM:

LUNG, RIGHT MIDDLE LOBE LESION, RESECTION:

-AFB AND GMS STAINS OF THE CALCIFIED GRANULOMA ARE NEGATIVE.

Source: NCI Genomic Data Commons file 26f232e3-dfc3-491f-bf88-1df3b7e5ca00 (TCGA-60-2704.5FC80D98-89C6-4BB4-BBF7-639F1D2C5647.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).